Somatic mutation profile of tumor specimen TCGA-VP-A87H-01A (aliquot TCGA-VP-A87H-01A-11D-A34U-08) from TCGA case TCGA-VP-A87H, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 76.8 years (28,060 days).
Specimen TCGA-VP-A87H-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 450486ab-de29-44ae-9e0c-d0626099128f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VP-A87H-10A (Blood Derived Normal), aliquot TCGA-VP-A87H-10A-01D-A34X-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4660ae20-ab4f-4fda-bbe9-fdba69cde84a

The open-access MAF lists 25 somatic variants for this specimen: 19 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 16, Silent 6, Frame Shift Del 2, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CTNNB1 | c.98C>A p.S33Y | Missense Mutation (SNP) | VAF 10/52 reads (19%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121913400, COSV62687839, COSV62688300, COSV62688644; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- PIK3CA | c.1624G>A p.E542K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.912); catalogued as rs121913273, CM153078, COSV55873227, COSV55894248; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- SPOP | c.397T>G p.F133V | Missense Mutation (SNP) | VAF 41/131 reads (31%) | hotspot (GDC flag); SIFT deleterious (0.03); PolyPhen possibly damaging (0.554); catalogued as rs1057519966, COSV61652724, COSV61652960, COSV61653269; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- COBLL1 | c.2168C>T p.S723L (on ENST00000392717; = p.S685L on NM_014900.5) | Missense Mutation (SNP) | VAF 34/119 reads (29%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV52066097; called by muse, mutect2, varscan2
- DDX60 | c.2209C>T p.R737W | Missense Mutation (SNP) | VAF 16/62 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs767373127, COSV67095656; called by muse, mutect2, varscan2
- HNF1A | c.29C>T p.T10M | Missense Mutation (SNP) | VAF 13/77 reads (17%) | SIFT deleterious (0.05); PolyPhen benign (0.231); catalogued as rs774637975, CM064303, COSV99982822; ClinVar: conflicting interpretations of pathogenicity; called by muse, mutect2, varscan2
- LONRF1 | c.1970G>T p.G657V | Missense Mutation (SNP) | VAF 28/80 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101238249; called by muse, mutect2, varscan2
- MUC6 | c.3407C>T p.T1136M | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.913); catalogued as rs373492122; called by mutect2, varscan2
- MYO9A | c.1360A>G p.I454V | Missense Mutation (SNP) | VAF 19/58 reads (33%) | SIFT tolerated (0.67); PolyPhen benign (0.003); catalogued as rs749827517, COSV100613975; called by muse, mutect2, varscan2
- NPAT | c.812T>C p.L271S | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99586226; called by muse, mutect2, varscan2
- RMDN1 | c.860A>G p.K287R | Missense Mutation (SNP) | VAF 52/154 reads (34%) | SIFT tolerated (0.44); PolyPhen benign (0.005); catalogued as COSV101288468; called by muse, mutect2, varscan2
- RYR3 | c.10184G>A p.R3395Q (on ENST00000389232; = p.R3396Q on NM_001036.6) | Missense Mutation (SNP) | VAF 15/37 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs771747010, COSV66777075; called by muse, mutect2, varscan2
- SEZ6L2 | c.1472G>A p.C491Y (on ENST00000308713 / NM_001114099.3; = p.C421Y on NM_012410.4) | Missense Mutation (SNP) | VAF 16/112 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); catalogued as COSV100435665; called by muse, mutect2, varscan2
- TAS2R19 | c.31A>G p.I11V | Missense Mutation (SNP) | VAF 4/31 reads (13%) | SIFT tolerated (0.16); PolyPhen benign (0.26); catalogued as rs754615861, COSV101115252; called by muse, mutect2, varscan2
- UBALD2 | c.190A>G p.T64A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.994); catalogued as COSV99429491; called by muse, mutect2
- ZNF148 | c.553C>A p.H185N | Missense Mutation (SNP) | VAF 40/105 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100642152; called by muse, mutect2, varscan2
- ACADVL | c.1431dup p.M478Yfs*84 | Frame Shift Ins (INS) | VAF 10/50 reads (20%) | called by mutect2, pindel, varscan2
- FAT1 | c.10525_10526del p.D3509Sfs*11 | Frame Shift Del (DEL) | VAF 8/44 reads (18%) | called by mutect2, pindel, varscan2
- OR2V2 | c.481del p.M161Wfs*3 | Frame Shift Del (DEL) | VAF 34/161 reads (21%) | called by mutect2, pindel, varscan2
- ASNS | c.594C>T p.S198= | Silent (SNP) | VAF 32/114 reads (28%) | catalogued as rs527301530, COSV51554494, COSV51556557; ClinVar: likely benign; called by muse, mutect2, varscan2
- CALHM1 | c.408C>T p.S136= | Silent (SNP) | VAF 8/34 reads (24%) | catalogued as rs554951738, COSV100324369, COSV100324384; called by muse, mutect2, varscan2
- CYP27A1 | c.585G>A p.E195= | Silent (SNP) | VAF 23/125 reads (18%) | catalogued as COSV99298651; called by muse, mutect2, varscan2
- DOP1B | c.2436G>C p.V812= | Silent (SNP) | VAF 17/136 reads (13%) | catalogued as COSV101215667; called by muse, mutect2, varscan2
- MACF1 | c.6519T>C p.F2173= | Silent (SNP) | VAF 16/54 reads (30%) | catalogued as COSV99245876; called by muse, mutect2, varscan2
- TMC7 | c.873C>T p.F291= | Silent (SNP) | VAF 47/82 reads (57%) | catalogued as rs772852930, COSV100432681; called by muse, mutect2, varscan2
